Somatic mutation profile of tumor specimen TCGA-RC-A6M3-01A (aliquot TCGA-RC-A6M3-01A-11D-A32G-10) from TCGA case TCGA-RC-A6M3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 24.4 years (8,899 days).
Specimen TCGA-RC-A6M3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a44608aa-06aa-47b0-baa3-301680902287.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A6M3-10A (Blood Derived Normal), aliquot TCGA-RC-A6M3-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c1c18bf-e971-42ec-bddd-1354bffc4c20

The open-access MAF lists 82 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1385T>C p.L462S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940089; called by muse, mutect2, varscan2
- ARHGAP10 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100330912; called by muse, mutect2, varscan2
- ARHGEF17 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99734922; called by muse, mutect2, varscan2
- CCDC146 | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV99592177; called by muse, mutect2, varscan2
- CHD6 | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991214617, COSV100497786; called by muse, mutect2, varscan2
- COL12A1 | c.3886A>G p.M1296V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs746366215, COSV100485422; called by muse, mutect2, varscan2
- COPA | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV99614671; called by muse, mutect2, varscan2
- COPS4 | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100018359; called by muse, mutect2, varscan2
- CSNK1G2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); catalogued as COSV99729585; called by muse, mutect2
- DDX47 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100774491; called by muse, mutect2, varscan2
- DNAH9 | c.10627T>C p.C3543R | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99304227; called by muse, mutect2, varscan2
- EIF4G3 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99943281; called by muse, mutect2, varscan2
- FAM184A | c.1343A>G p.E448G | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV100137396; called by muse, mutect2, varscan2
- FN1 | c.3553A>G p.N1185D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs746992481, COSV100116129; called by muse, mutect2, varscan2
- GRIP1 | c.1021G>C p.A341P | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.062); catalogued as COSV99668094; called by muse, mutect2, varscan2
- IDO2 | c.278G>C p.G93A (on ENST00000389060; = p.G106A on NM_194294.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.831); catalogued as COSV58423662; called by muse, mutect2, varscan2
- IL27RA | c.376+1G>A p.X126_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99651925; called by muse, mutect2, varscan2
- ITGAD | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101210330; called by muse, mutect2, varscan2
- ITGB3 | c.1032T>A p.Y344* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV101457543; called by muse, mutect2
- KLHL13 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53245707; called by muse, mutect2, varscan2
- KRT82 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.053); catalogued as COSV57785776, COSV99233392; called by muse, mutect2
- KRT85 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as COSV57737964, COSV99225158; called by muse, mutect2, varscan2
- KRTAP9-2 | c.523T>G p.*175Gext*24 | Nonstop Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100893116; called by muse, mutect2, varscan2
- LGSN | c.457T>G p.L153V | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV101040279; called by muse, mutect2, varscan2
- LRRC15 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs780088793, COSV100752548; called by muse, mutect2, varscan2
- MED14 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 81/145 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100247313; called by muse, mutect2, varscan2
- NDST3 | c.1881C>G p.S627R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99629631; called by muse, mutect2, varscan2
- NETO1 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55005214; called by muse, mutect2, varscan2
- NRDC | c.2471A>G p.E824G | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100703103; called by muse, mutect2, varscan2
- OR7D2 | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100712945; called by muse, mutect2, varscan2
- OR9K2 | c.949A>G p.N317D (on ENST00000305377; = p.N295D on NM_001005243.1) | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59533046, COSV59533681; called by muse, mutect2, varscan2
- PCDH11Y | c.2090A>T p.D697V (on ENST00000400457 / NM_032973.2; = p.D686V on NM_032971.3) | Missense Mutation (SNP) | VAF 142/222 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99290612; called by muse, varscan2
- PER3 | c.2468G>A p.G823D | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs934199222, COSV100728215; called by muse, mutect2, varscan2
- PPP3CA | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs764832679, COSV59921708; called by muse, mutect2, varscan2
- PRRC2B | c.5027G>T p.S1676I | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100260861; called by muse, mutect2, varscan2
- PYHIN1 | c.1017G>T p.R339S | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV100932321; called by muse, mutect2, varscan2
- REC114 | c.176A>C p.E59A | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100461077; called by muse, mutect2, varscan2
- RHOU | c.257T>A p.F86Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.148); catalogued as COSV100797133; called by muse, mutect2, varscan2
- RNF216 | c.1655C>G p.S552C (on ENST00000425013 / NM_207116.3; = p.S609C on NM_207111.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101111266, COSV66290529; called by muse, mutect2, varscan2
- RYR2 | c.2885A>G p.K962R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.346); catalogued as COSV100768105; called by muse, mutect2, varscan2
- SARDH | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100060465; called by muse, mutect2, varscan2
- SEMA6A | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99145541; called by muse, mutect2, varscan2
- SGCZ | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs1342150245, COSV66020833, COSV66053884; called by muse, mutect2, varscan2
- SH2B2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1178024770, COSV100159231; called by muse, mutect2, varscan2
- SNAP91 | c.2470G>C p.V824L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV99534458; called by muse, mutect2, varscan2
- STAG1 | c.3763A>C p.M1255L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99364473; called by muse, mutect2, varscan2
- STK25 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as COSV100346048; called by muse, mutect2, varscan2
- TRIM72 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV59069816, COSV59070354; called by muse, mutect2, varscan2
- TRPA1 | c.2056C>A p.L686I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100083218; called by muse, mutect2, varscan2
- UBA7 | c.1045G>C p.V349L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100339601; called by muse, mutect2, varscan2
- ZAP70 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99385218; called by mutect2, varscan2
- ZFP28 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100019272, COSV56734974; called by muse, mutect2, varscan2
- ZFYVE9 | c.2330A>C p.N777T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV55095151, COSV99819400; called by muse, mutect2, varscan2
- ZNF17 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100299915; called by muse, mutect2, varscan2
- ZNF429 | c.1501A>G p.K501E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.352); catalogued as COSV100641794; called by muse, mutect2, varscan2
- ZNF454 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100194625; called by muse, mutect2
- ZNF470 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100401084, COSV100401428; called by muse, mutect2, varscan2
- ZNF624 | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100257017; called by muse, mutect2, varscan2
- ADGRA2 | c.1313C>A p.S438Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARAP1 | c.3347_3348insTCCCA p.Q1116Hfs*44 (on ENST00000393609 / NM_001040118.2; = p.Q871Hfs*44 on NM_015242.4) | Frame Shift Ins (INS) | VAF 19/39 reads (49%) | called by mutect2, pindel, varscan2
- KIFC1 | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- PDGFC | c.37_46del p.L13Rfs*11 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- AP2A1 | c.2313G>A p.Q771= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100571000; called by muse, mutect2, varscan2
- ARHGEF11 | c.2232G>A p.V744= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100168292; called by muse, mutect2, varscan2
- CEMIP2 | c.1176T>C p.S392= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100987238; called by muse, mutect2, varscan2
- CHMP6 | c.594G>A p.V198= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100289395; called by muse, mutect2, varscan2
- CHUK | c.9G>T p.R3= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100821453; called by muse, mutect2, varscan2
- FBN3 | c.5322C>T p.C1774= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99559898; called by muse, mutect2, varscan2
- GSTO1 | c.489C>T p.T163= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs762022730, COSV100086587; called by muse, mutect2, varscan2
- HSDL1 | c.444G>A p.L148= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99550266; called by muse, mutect2, varscan2
- IFT140 | c.1488G>A p.T496= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1383563444, COSV101276293; called by muse, mutect2, varscan2
- MPL | c.489T>C p.D163= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV100991332; called by muse, mutect2, varscan2
- OR5M1 | c.720G>A p.T240= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs1278658497, COSV101591532; called by muse, mutect2, varscan2
- OXSM | c.648G>T p.V216= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as rs929865831, COSV99771916; called by muse, mutect2, varscan2
- PCDHGB2 | c.1947A>G p.G649= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54066165; called by muse, mutect2, varscan2
- RNASE1 | c.255C>T p.V85= | Silent (SNP) | VAF 62/124 reads (50%) | catalogued as COSV100564468; called by muse, mutect2, varscan2
- RP1 | c.2793T>C p.P931= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV99606320; called by muse, mutect2, varscan2
- SHROOM3 | c.1014A>C p.S338= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99933567; called by muse, mutect2, varscan2
- SOX21 | c.597C>T p.T199= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100977883; called by muse, varscan2
- TBX4 | c.1113T>A p.P371= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99539895; called by muse, mutect2, varscan2
- ZPBP | c.999A>T p.G333= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99249086; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1873G>C | Intron (SNP) | VAF 30/81 reads (37%) | catalogued as rs200463796, COSV57685155; called by muse, mutect2, varscan2
